Somatic mutation profile of tumor specimen TCGA-D3-A51R-06A (aliquot TCGA-D3-A51R-06A-11D-A25O-08) from TCGA case TCGA-D3-A51R, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.9 years (22,989 days).
Specimen TCGA-D3-A51R-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70642871-c8a6-45d0-8740-97bd83abdacc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51R-10A (Blood Derived Normal), aliquot TCGA-D3-A51R-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2eac9fa3-8625-430d-adf8-0ab295063c82

The open-access MAF lists 862 somatic variants for this specimen: 553 protein-altering or splice-affecting, 289 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 505, Silent 289, Nonsense Mutation 33, Intron 10, Splice Region 7, RNA 6, Splice Site 4, 5'Flank 2, Frame Shift Del 2, 3'Flank 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (750 of 862; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYPN | c.2704-1G>A p.X902_splice | Splice Site (SNP) | VAF 10/21 reads (48%) | catalogued as rs865921466, COSV62731218; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 152/214 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.40399C>T p.R13467* (on ENST00000591111; = p.R6043* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as rs1060500405, COSV59862588; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV50956972; called by muse, mutect2, varscan2
- ABCA8 | c.4142G>A p.G1381E | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52193157; called by muse, mutect2, varscan2
- ABCA8 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as COSV52193187; called by muse, mutect2, varscan2
- ABCA9 | c.2653T>A p.Y885N | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV60619749; called by muse, mutect2, varscan2
- ABCA9 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV60619760; called by muse, mutect2, varscan2
- ABCB10 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60619361; called by muse, mutect2, varscan2
- ABCB10 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs745661382, COSV60619375; called by muse, mutect2, varscan2
- ABCC3 | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0.068); catalogued as COSV53316775; called by muse, mutect2, varscan2
- ABCC6 | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM080025, COSV52740899; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68343498; called by muse, mutect2, varscan2
- ABI3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs369657954; called by muse, mutect2
- AC127029.3 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV60110139; called by muse, mutect2, varscan2
- ACAN | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.118); catalogued as COSV61355052; called by muse, mutect2, varscan2
- ACSM1 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 127/319 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1471855367, COSV54632711, COSV54638023; called by muse, mutect2, varscan2
- ADAD1 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.238); catalogued as rs1367631600, COSV56641111; called by muse, mutect2, varscan2
- ADAM20 | c.1247A>C p.E416A | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56453964, COSV56455859; called by muse, mutect2, varscan2
- ADAM7 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751999467, COSV51534385; called by muse, mutect2, varscan2
- ADAMTS12 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs144000005, COSV61254500; called by muse, mutect2, varscan2
- ADAMTS19 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs188910013, COSV50731320; called by muse, mutect2, varscan2
- ADAMTS19 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as COSV50731321; called by muse, mutect2, varscan2
- ADAMTS19 | c.3138G>A p.W1046* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV50731323; called by muse, mutect2, varscan2
- ADCY1 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1182519617, COSV52029423; called by muse, mutect2, varscan2
- ADD2 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1553368453, COSV100035199; called by muse, mutect2, varscan2
- ADGRB3 | c.3686G>A p.G1229E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1254198978, COSV53233042, COSV53257692; called by muse, mutect2, varscan2
- ADGRE3 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV53728052; called by muse, mutect2, varscan2
- ADGRG3 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs765107047, COSV59649909; called by muse, mutect2, varscan2
- AFP | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV56923659; called by muse, mutect2
- AGBL2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs745526604, COSV54089752; called by muse, mutect2, varscan2
- AGXT2 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.183); catalogued as rs752126134, COSV51483534; called by muse, mutect2, varscan2
- AIPL1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.334); catalogued as COSV51505766; called by muse, mutect2, varscan2
- ALDH16A1 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53192313; called by muse, mutect2, varscan2
- ALG2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 51/53 reads (96%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1276667626, COSV53058609; called by muse, mutect2, varscan2
- ALPK2 | c.3683G>A p.G1228E | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as COSV64489774; called by muse, mutect2, varscan2
- AMER1 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 10/13 reads (77%) | catalogued as COSV57653741; called by muse, mutect2, varscan2
- ANGPT1 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52429193; called by muse, mutect2, varscan2
- ANGPT1 | c.707A>G p.Q236R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs774473514, COSV52429206; called by muse, mutect2, varscan2
- ANK3 | c.10450A>C p.S3484R | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV55042394; called by muse, mutect2, varscan2
- ANK3 | c.6551C>T p.P2184L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV55042400; called by muse, mutect2, varscan2
- ANKRD34B | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs779716600, COSV58613250; called by muse, mutect2, varscan2
- ANKRD45 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as COSV60960016; called by muse, mutect2, varscan2
- ANO2 | c.2614C>T p.Q872* (on ENST00000356134 / NM_001278597.3; = p.Q876* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV59006015; called by muse, mutect2, varscan2
- ANO2 | c.610C>T p.P204S (on ENST00000356134 / NM_001278597.3; = p.P208S on NM_001278596.3) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59006036; called by muse, mutect2, varscan2
- ANO4 | c.725G>A p.R242K (on ENST00000392977 / NM_001286615.2; = p.R207K on NM_178826.4) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.376); catalogued as COSV54583672; called by muse, mutect2, varscan2
- ANO7 | c.2134+1G>A p.X712_splice (on ENST00000274979; = p.X658_splice on NM_001370694.2) | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99237939; called by muse, mutect2
- APC | c.4976A>T p.D1659V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57320790; called by muse, mutect2, varscan2
- APOB | c.12731C>T p.S4244F | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV51921429; called by muse, mutect2, varscan2
- ARAP1 | c.3579C>T p.V1193= (on ENST00000393609 / NM_001040118.2; = p.V948= on NM_015242.4) | Splice Region (SNP) | VAF 45/46 reads (98%) | catalogued as COSV61989138; called by muse, mutect2, varscan2
- ARMC4 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53462302; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 30/33 reads (91%) | catalogued as COSV63436898; called by muse, mutect2, varscan2
- ASB4 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV57942622; called by muse, mutect2, varscan2
- ASH1L | c.2225T>A p.F742Y | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV64204950; called by muse, mutect2, varscan2
- ATF4 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57477487; called by muse, mutect2, varscan2
- ATP2A1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs767065944, COSV63919801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7A | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1030215501, COSV58441778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7B | c.4187C>T p.T1396M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs528603867, COSV54434713, COSV54434723; called by mutect2, varscan2
- ATRNL1 | c.2054G>A p.W685* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV61796088; called by muse, mutect2, varscan2
- BCL11B | c.1715G>A p.G572E (on ENST00000357195 / NM_001282237.2; = p.G501E on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.63); catalogued as COSV61732859; called by muse, mutect2, varscan2
- BDNF | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 90/100 reads (90%) | SIFT tolerated (0.26); PolyPhen benign (0.203); catalogued as rs1295890250, COSV59232895; called by muse, mutect2, varscan2
- BLK | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52049054; called by muse, mutect2, varscan2
- BMX | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV59590037; called by muse, mutect2, varscan2
- BNC1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61756371; called by muse, mutect2, varscan2
- BORA | c.1543G>C p.E515Q (on ENST00000613797; = p.E440Q on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV64694782; called by muse, mutect2, varscan2
- BPIFC | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55910533; called by muse, mutect2, varscan2
- BTAF1 | c.705T>G p.N235K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.134); catalogued as COSV56429259; called by muse, mutect2, varscan2
- BTBD16 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs202210822, COSV53260423; called by muse, mutect2, varscan2
- BTNL8 | c.877G>A p.D293N (on ENST00000340184 / NM_001040462.3; = p.G336E on NM_024850.2) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99180447; called by muse, mutect2, varscan2
- C10orf71 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs763388167, COSV60503923; called by muse, mutect2, varscan2
- C12orf40 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV61129131, COSV61129258; called by muse, mutect2, varscan2
- C1QB | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV59244915; called by muse, mutect2, varscan2
- C2CD3 | c.5377C>T p.P1793S | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV58088964; called by muse, mutect2, varscan2
- C2orf16 | c.5566C>T p.P1856S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.349); catalogued as rs754181252, COSV100820725; called by muse, mutect2, varscan2
- C2orf16 | c.5567C>T p.P1856L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100820726, COSV62678482; called by muse, mutect2, varscan2
- C7orf31 | c.769T>C p.W257R | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs1159811345, COSV52215852; called by muse, mutect2, varscan2
- C8orf74 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV58753444; called by muse, mutect2, varscan2
- CACNA1G | c.7115C>A p.P2372Q | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.003); catalogued as COSV61719768; called by muse, mutect2, varscan2
- CACNG3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs868820485, COSV50063824; called by muse, mutect2, varscan2
- CADM3 | c.578C>T p.S193L (on ENST00000368125 / NM_001127173.3; = p.S227L on NM_021189.5) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.455); catalogued as rs1179781491, COSV63683490; called by muse, mutect2, varscan2
- CADPS2 | c.3516G>A p.M1172I | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV57347222; called by muse, mutect2, varscan2
- CAMTA1 | c.4736G>A p.S1579N | Missense Mutation (SNP) | VAF 105/266 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV57879529; called by muse, mutect2, varscan2
- CAPZA3 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764011869, COSV56848343, COSV56851939; called by muse, mutect2, varscan2
- CBFA2T3 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs761326155, COSV51922500; called by muse, mutect2, varscan2
- CBY2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752329859, COSV60117047; called by muse, mutect2, varscan2
- CCDC172 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769448112, COSV60936457, COSV60936505, COSV60938265; called by muse, mutect2, varscan2
- CCDC191 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 49/107 reads (46%) | catalogued as rs755444201, COSV55669772; called by muse, mutect2, varscan2
- CCDC33 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV58347659, COSV58350883; called by muse, mutect2, varscan2
- CCDC63 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57526559; called by muse, mutect2, varscan2
- CCM2L | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.268); catalogued as COSV52948753; called by muse, mutect2, varscan2
- CCR8 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58336647; called by muse, mutect2, varscan2
- CD163 | c.3297G>A p.M1099I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.914); catalogued as COSV63128994; called by muse, mutect2, varscan2
- CD1B | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63803728; called by muse, mutect2, varscan2
- CD2 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV65643828; called by muse, mutect2, varscan2
- CDH13 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs1193690872, COSV51786661, COSV51799691; called by muse, mutect2, varscan2
- CDH4 | c.1050G>A p.E350= | Splice Region (SNP) | VAF 68/108 reads (63%) | catalogued as COSV64640784; called by muse, mutect2, varscan2
- CDT1 | c.1387A>G p.S463G | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs748552177, COSV56347080; called by muse, mutect2, varscan2
- CEACAM5 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.784); catalogued as COSV55750352; called by muse, mutect2, varscan2
- CELF6 | c.523+1G>A p.X175_splice | Splice Site (SNP) | VAF 21/37 reads (57%) | catalogued as COSV54715020; called by muse, mutect2, varscan2
- CENPJ | c.2710C>T p.Q904* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV101121488; called by muse, mutect2, varscan2
- CEP43 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV100835602, COSV62760335; called by muse, mutect2, varscan2
- CERKL | c.1172C>T p.S391L (on ENST00000339098 / NM_001030311.2; = p.S365L on NM_201548.5) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs866794217, COSV59202458, COSV59202788, COSV59214606; called by muse, mutect2, varscan2
- CES1 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV62085118; called by muse, mutect2, varscan2
- CES5A | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51863196; called by muse, mutect2, varscan2
- CFAP44 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55608130; called by muse, mutect2, varscan2
- CFAP54 | c.5471G>A p.R1824Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs558062906, COSV61570271; called by muse, mutect2, varscan2
- CHD5 | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV52406711; called by muse, mutect2, varscan2
- CHGB | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377220442; called by muse, mutect2
- CHGB | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV66759458; called by muse, mutect2, varscan2
- CHGB | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs868039492, COSV100972954, COSV66759464; called by muse, mutect2, varscan2
- CHL1 | c.1381G>A p.E461K (on ENST00000397491 / NM_001253387.1; = p.E477K on NM_006614.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs766081792, COSV56585259; called by muse, mutect2, varscan2
- CIC | c.1768T>C p.F590L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV50546531; called by muse, mutect2, varscan2
- CLCN1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV58367101; called by muse, mutect2, varscan2
- CLEC18B | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV60576267; called by muse, mutect2, varscan2
- CLK2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs146292560, COSV62876402, COSV62877910; called by muse, mutect2, varscan2
- CLRN2 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55549094; called by muse, mutect2, varscan2
- CMYA5 | c.6971G>A p.G2324D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV71404010; called by muse, mutect2, varscan2
- CNOT3 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55359762; called by muse, mutect2, varscan2
- COL21A1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152222; called by muse, mutect2, varscan2
- COL21A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs267601087, COSV55152247; called by muse, mutect2, varscan2
- COPA | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs1396829399, COSV54097252; called by muse, mutect2
- CPM | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100614993; called by muse, mutect2, varscan2
- CPM | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.22); catalogued as COSV100614994; called by muse, mutect2, varscan2
- CRCT1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 20/37 reads (54%) | PolyPhen probably damaging (0.917); catalogued as rs1010002256, COSV57499771; called by muse, mutect2, varscan2
- CREB3L4 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55131163; called by muse, mutect2, varscan2
- CRYGS | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57192031, COSV57192639; called by muse, mutect2, varscan2
- CSAG1 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 87/92 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV63399815; called by muse, mutect2, varscan2
- CSHL1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs373669578, COSV51987067; called by muse, mutect2, varscan2
- CSMD1 | c.2198G>A p.G733E (on ENST00000520002; = p.G732E on NM_033225.6) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148719, COSV59276812; called by muse, mutect2, varscan2
- CSMD2 | c.8803T>C p.S2935P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.552); catalogued as COSV53874447; called by muse, mutect2, varscan2
- CSMD3 | c.6299G>A p.W2100* (on ENST00000297405 / NM_001363185.1; = p.W1996* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV52091146, COSV99821314; called by muse, mutect2, varscan2
- CTHRC1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as rs147175675, COSV57715602; called by muse, mutect2, varscan2
- CTNND2 | c.2399G>A p.G800D | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58861687; called by muse, mutect2, varscan2
- CYLC2 | c.765T>G p.D255E | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66335866, COSV66340395; called by muse, mutect2, varscan2
- CYP24A1 | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV53772680; called by muse, mutect2, varscan2
- CYP2C18 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs770145786, COSV53669438; called by muse, mutect2, varscan2
- CYP2C19 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.245); catalogued as rs1321737607, COSV64906627; called by muse, mutect2, varscan2
- CYP2D6 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as COSV62242763; called by muse, mutect2, varscan2
- CYP4F12 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV61171875; called by muse, mutect2, varscan2
- CYP4X1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64149533; called by muse, mutect2, varscan2
- DAAM1 | c.731T>C p.M244T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62833819; called by muse, mutect2, varscan2
- DCAF4L2 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as COSV60476153, COSV60479913; called by muse, mutect2, varscan2
- DCC | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV59081068, COSV59137171; called by muse, mutect2, varscan2
- DCSTAMP | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV52575818, COSV99034295; called by muse, mutect2, varscan2
- DIRAS2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 64/71 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65370298; called by muse, mutect2, varscan2
- DKK2 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53393361; called by muse, mutect2, varscan2
- DLG5 | c.4070C>T p.S1357L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV64946518; called by muse, mutect2, varscan2
- DMBT1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780912281, COSV57532698; called by muse, mutect2, varscan2
- DMBT1 | c.6622C>T p.R2208* (on ENST00000338354 / NM_001377530.1; = p.R1451* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as rs750755212, COSV57532724; called by muse, mutect2, varscan2
- DMBX1 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV63601586; called by muse, mutect2
- DNAH5 | c.13469G>A p.G4490E | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54201333; called by muse, mutect2, varscan2
- DNAH5 | c.11811G>A p.W3937* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV54201354; called by muse, mutect2, varscan2
- DNAH7 | c.9013G>A p.E3005K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293205953, COSV56750027; called by muse, mutect2, varscan2
- DNAH7 | c.6823G>A p.D2275N | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.169); catalogued as COSV56750036; called by muse, mutect2, varscan2
- DNAH8 | c.8884C>T p.R2962C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575613410, COSV100543317, COSV59421538, COSV59422300; called by muse, mutect2, varscan2
- DNAI2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1228330378, COSV56756534; called by muse, mutect2, varscan2
- DNAJC5B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs141686243, COSV52535470; called by muse, mutect2, varscan2
- DOK6 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as rs376645571; called by muse, mutect2, varscan2
- DST | c.21667C>T p.R7223C (on ENST00000361203 / NM_001374722.1; = p.R4920C on NM_015548.5) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527354100, COSV54995124; called by muse, mutect2, varscan2
- DST | c.246C>T p.P82= | Splice Region (SNP) | VAF 8/15 reads (53%) | catalogued as COSV56796648; called by muse, mutect2, varscan2
- ECH1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55488529; called by muse, mutect2, varscan2
- ECT2L | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs1447701496, COSV62882521; called by muse, mutect2, varscan2
- EDC4 | c.767T>G p.V256G | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV62765298; called by muse, mutect2, varscan2
- EIF4B | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.164); catalogued as COSV50401482; called by muse, mutect2, varscan2
- ELAVL4 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV63913835; called by muse, varscan2
- ENPEP | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54446456; called by muse, mutect2, varscan2
- EPHB1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67653010; called by muse, mutect2, varscan2
- EPHB6 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.105); catalogued as COSV63890233; called by muse, mutect2, varscan2
- ERGIC3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as rs868448649, COSV54135421; called by muse, mutect2, varscan2
- EXOG | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as COSV55062545; called by muse, mutect2, varscan2
- EYA4 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as COSV62044779; called by muse, mutect2, varscan2
- F8 | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM062669, CM0911140, COSV64269284; called by muse, mutect2, varscan2
- FAM117A | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.898); catalogued as COSV53630353; called by muse, mutect2, varscan2
- FAM135B | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs267601785, COSV52702171; called by muse, mutect2, varscan2
- FAM135B | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV52702200; called by muse, mutect2, varscan2
- FAM177B | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1166779755, COSV62600855; called by muse, mutect2, varscan2
- FAM217A | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs764997056, COSV51158867; called by muse, mutect2, varscan2
- FAM83C | c.1844C>T p.S615L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs775523670, COSV65581844; called by muse, mutect2, varscan2
- FAT4 | c.8711G>A p.G2904E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58669776; called by muse, mutect2, varscan2
- FER1L6 | c.3142G>A p.E1048K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs200333104, COSV67547702; called by muse, mutect2, varscan2
- FFAR1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.467); catalogued as rs143187042, COSV99322802; called by muse, mutect2, varscan2
- FGF20 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51660744; called by muse, mutect2
- FGFR2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV60638343; called by muse, mutect2, varscan2
- FLG | c.7484C>T p.T2495I | Missense Mutation (SNP) | VAF 135/501 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs775080390, COSV64235630; called by muse, mutect2, varscan2
- FLG | c.6005G>A p.G2002E | Missense Mutation (SNP) | VAF 216/1118 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.587); catalogued as rs767171957, COSV64235636; called by muse, mutect2, varscan2
- FLG2 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 103/344 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV66166296; called by muse, mutect2, varscan2
- FLYWCH1 | c.1841C>T p.S614F (on ENST00000253928 / NM_001308068.2; = p.S613F on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54143092; called by muse, mutect2, varscan2
- FNDC1 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV51929729, COSV51935656; called by muse, mutect2, varscan2
- FOXA2 | c.730G>A p.E244K (on ENST00000377115 / NM_153675.3; = p.E250K on NM_021784.5) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV65795534, COSV65796814; called by muse, mutect2, varscan2
- FREM2 | c.7488G>A p.M2496I | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54826764; called by muse, mutect2, varscan2
- FSHB | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV54221267; called by muse, mutect2, varscan2
- FYB1 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV60940176, COSV60947622; called by muse, mutect2, varscan2
- FYB2 | c.2163C>T p.F721= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as COSV58582527; called by muse, mutect2
- GFAP | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs770249831, COSV53648526; called by mutect2, varscan2
- GFRA3 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as COSV99218342, COSV99218430; called by muse, mutect2, varscan2
- GHR | c.611G>A p.W204* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV50105630; called by muse, varscan2
- GHR | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs754420410, COSV50105634; called by muse, mutect2, varscan2
- GHRHR | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV58195427; called by muse, mutect2, varscan2
- GIMAP8 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56233878; called by muse, mutect2, varscan2
- GJA10 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65354708; called by muse, mutect2, varscan2
- GLI3 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV67884655; called by muse, mutect2, varscan2
- GLIPR1L1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56880283; called by muse, mutect2, varscan2
- GLP1R | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64714118, COSV64714630; called by muse, mutect2, varscan2
- GOLGA6A | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as rs1240048327, COSV51803784; called by mutect2, varscan2
- GPR148 | c.89A>C p.Q30P | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59307457; called by muse, mutect2, varscan2
- GPR158 | c.3484C>T p.Q1162* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV66264470; called by muse, mutect2, varscan2
- GPRC6A | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775109241, COSV59951289; called by muse, mutect2
- GREM2 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58946012; called by muse, mutect2, varscan2
- GRID2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56168073; called by muse, mutect2, varscan2
- GRM3 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 97/209 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1367849365, COSV64466494; called by muse, mutect2, varscan2
- GRM3 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64466501; called by muse, mutect2, varscan2
- GUCA1C | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1265768088, COSV51712957; called by muse, mutect2, varscan2
- H2BE1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55180742; called by muse, mutect2, varscan2
- HCFC1 | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV60068994; called by muse, mutect2, varscan2
- HCN3 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774471370, COSV61360208; called by muse, mutect2, varscan2
- HCRTR2 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.315); catalogued as COSV63793396; called by muse, mutect2, varscan2
- HELZ2 | c.4936G>A p.A1646T (on ENST00000467148 / NM_001037335.2; = p.A1077T on NM_033405.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.229); catalogued as COSV71295285; called by muse, mutect2, varscan2
- HMGA2 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV63589314; called by muse, mutect2, varscan2
- HSPA6 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.724); catalogued as rs755394706, COSV59059599; called by muse, mutect2, varscan2
- HUNK | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs141493785; called by muse, mutect2, varscan2
- HYDIN | c.6158C>T p.A2053V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99992425; called by muse, mutect2, varscan2
- IGDCC3 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV100030960; called by mutect2, varscan2
- IGF2BP1 | c.1405A>G p.R469G | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV51728453; called by muse, mutect2, varscan2
- IGHA2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1555452761; called by muse, mutect2, varscan2
- IGLV3-21 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs370319495; called by muse, mutect2, varscan2
- IKZF2 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.486); catalogued as rs867126895, COSV59575974; called by muse, mutect2, varscan2
- IKZF2 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs747620736, COSV59575984; called by muse, mutect2, varscan2
- IL18RAP | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51823687; called by muse, mutect2, varscan2
- IL23R | c.301T>C p.C101R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61372497; called by muse, mutect2, varscan2
- IL6ST | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1479022540, COSV61139490; called by muse, mutect2, varscan2
- IL7R | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV57405391; called by muse, mutect2, varscan2
- IMPA2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV52318591; called by muse, mutect2, varscan2
- ITGB3 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as rs955557532, COSV71383267; called by muse, mutect2, varscan2
- ITIH4 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV56571034; called by muse, mutect2, varscan2
- JADE1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs774236013, COSV56903821; called by muse, mutect2
- KANK4 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100443142; called by muse, mutect2, varscan2
- KAZALD1 | c.545G>A p.W182* | Nonsense Mutation (SNP) | VAF 22/36 reads (61%) | catalogued as COSV100930580; called by muse, mutect2, varscan2
- KCNB2 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV73048711; called by muse, mutect2, varscan2
- KCND2 | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as COSV58567523; called by muse, mutect2, varscan2
- KCNH7 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59782806, COSV59784490; called by muse, mutect2, varscan2
- KCTD8 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63584894; called by muse, mutect2, varscan2
- KDM5C | c.4610C>T p.S1537L | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.019); catalogued as rs782534108, COSV64762395; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIAA1958 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1471639672, COSV61721253; called by muse, mutect2, varscan2
- KIF25 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV63026319; called by muse, mutect2, varscan2
- KIF3C | c.1187A>T p.K396M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV53097394; called by muse, mutect2, varscan2
- KIFAP3 | c.451C>G p.R151G | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV63030572, COSV63037674; called by muse, mutect2, varscan2
- KIRREL3 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73104121; called by muse, mutect2, varscan2
- KLHL13 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53244149; called by muse, mutect2, varscan2
- KLHL31 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV63881271; called by muse, mutect2, varscan2
- KLHL5 | c.522G>A p.R174= | Splice Region (SNP) | VAF 21/49 reads (43%) | catalogued as rs1476132383, COSV54671080; called by muse, mutect2, varscan2
- KLRD1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100282157; called by muse, mutect2, varscan2
- KMT2B | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV52889172; called by muse, mutect2, varscan2
- KNG1 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV53975890; called by muse, mutect2, varscan2
- KRBA1 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV99752428; called by muse, mutect2, varscan2
- KRT28 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as rs866739949, COSV60683384; called by muse, mutect2, varscan2
- KRT77 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.133); catalogued as COSV59238161; called by muse, mutect2, varscan2
- KYNU | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV51578322; called by muse, mutect2, varscan2
- LACRT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57687688; called by muse, mutect2, varscan2
- LAMA2 | c.3991G>A p.D1331N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.127); catalogued as COSV70337084; called by muse, mutect2, varscan2
- LAMB3 | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61914994; called by muse, mutect2, varscan2
- LATS1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53585598; called by muse, mutect2, varscan2
- LCK | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60738336; called by muse, mutect2, varscan2
- LILRA1 | c.904A>C p.N302H | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1223832053; called by muse, mutect2
- LILRB5 | c.1447C>T p.R483W (on ENST00000449561 / NM_001081442.3; = p.R482W on NM_006840.5) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs752859717, COSV60254171, COSV60255683; called by muse, mutect2, varscan2
- LIMK2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.182); catalogued as rs1279238051, COSV59181198; called by muse, mutect2, varscan2
- LIN28B | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV61492673; called by muse, mutect2, varscan2
- LIPG | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.21); catalogued as rs750648857, COSV54294741; called by muse, mutect2
- LMX1A | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV54215910; called by muse, mutect2, varscan2
- LRATD1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs78327295, COSV54472034, COSV99707096; called by muse, mutect2, varscan2
- LRP1 | c.12767G>T p.C4256F | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99675272; called by muse, varscan2
- LRP2 | c.11894G>A p.G3965E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV55539010; called by muse, mutect2, varscan2
- LRRC66 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | catalogued as COSV58631772; called by muse, mutect2, varscan2
- LRRC75B | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV50637754; called by muse, mutect2
- LRRC8A | c.1750C>T p.L584F | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV52183637; called by muse, mutect2, varscan2
- LRRK2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV54170184; called by muse, mutect2, varscan2
- LRRN2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.034); catalogued as rs868345009, COSV65783164; called by muse, mutect2, varscan2
- LYN | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.57); catalogued as COSV70205278; called by muse, mutect2, varscan2
- MACROH2A2 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64706494; called by muse, mutect2, varscan2
- MAGEC3 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 31/34 reads (91%) | catalogued as rs1210749310, COSV53575606; called by muse, mutect2, varscan2
- MALL | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs764376036, COSV55599923; called by muse, mutect2, varscan2
- MALSU1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54978078; called by muse, mutect2, varscan2
- MAML3 | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV59070638; called by muse, varscan2
- MAP7 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 183/399 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs372519059, COSV63416761; called by muse, mutect2, varscan2
- MAP7D1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV60214819; called by muse, mutect2, varscan2
- MARCHF4 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56102458; called by muse, mutect2, varscan2
- MARCO | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as COSV59051354; called by muse, mutect2, varscan2
- MASP1 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV51457088; called by muse, mutect2, varscan2
- MBL2 | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as COSV64757877; called by muse, mutect2, varscan2
- MDH1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV51862244; called by muse, mutect2, varscan2
- MECOM | c.2771G>A p.G924E (on ENST00000468789 / NM_001105078.4; = p.G1112E on NM_004991.4) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52958387; called by muse, mutect2, varscan2
- MED18 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65790239; called by muse, mutect2, varscan2
- MEP1B | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV52495464; called by muse, mutect2, varscan2
- MGAM | c.4814C>T p.S1605F | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101527335, COSV72073448; called by muse, mutect2, varscan2
- MMP25 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755577652, COSV60678400; called by muse, mutect2, varscan2
- MOGAT1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV71479787, COSV71479937; called by muse, mutect2, varscan2
- MSTO1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs764173093, COSV99824158; called by muse, varscan2
- MTUS2 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs1210782354, COSV70912325; called by muse, mutect2, varscan2
- MUC16 | c.37886G>A p.R12629K | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV67440902; called by muse, mutect2, varscan2
- MUC16 | c.6758C>T p.S2253F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV67440914, COSV67481611; called by muse, mutect2, varscan2
- MUC17 | c.9674C>T p.T3225I | Missense Mutation (SNP) | VAF 245/503 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60279020; called by muse, mutect2, varscan2
- MUC17 | c.10480C>T p.P3494S | Missense Mutation (SNP) | VAF 214/476 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as COSV100072553, COSV100075716; called by muse, mutect2, varscan2
- MUC17 | c.10481C>T p.P3494L | Missense Mutation (SNP) | VAF 209/472 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as rs1279507590, COSV100072554; called by muse, mutect2, varscan2
- MUC17 | c.12409G>A p.G4137R | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV60279027; called by muse, mutect2, varscan2
- MYBPC1 | c.1169G>A p.R390Q (on ENST00000550270 / NM_206820.2; = p.R415Q on NM_002465.4) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs147400257; called by muse, mutect2, varscan2
- MYCN | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1431289688, COSV55257327; called by muse, mutect2, varscan2
- MYH1 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as COSV56843038; called by muse, mutect2, varscan2
- MYH11 | c.808C>G p.R270G | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55541820; called by muse, mutect2, varscan2
- MYH8 | c.3255G>A p.K1085= | Splice Region (SNP) | VAF 8/31 reads (26%) | catalogued as COSV67959126; called by muse, mutect2, varscan2
- MYL4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.744); catalogued as rs369894969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5C | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 57/64 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV55902147; called by muse, mutect2, varscan2
- MYSM1 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV68976867; called by muse, mutect2, varscan2
- NALCN | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as rs752215175, COSV51914992; called by muse, mutect2, varscan2
- NANOG | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs770105434, COSV57550774; called by muse, mutect2
- NCKAP1L | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs752560787, COSV53202875, COSV53205806; called by muse, mutect2, varscan2
- NDST1 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as rs1024786629, COSV55784658; called by muse, mutect2, varscan2
- NDST4 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.094); catalogued as COSV52107677; called by muse, mutect2, varscan2
- NEK8 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52042471, COSV52049188; called by muse, mutect2, varscan2
- NEUROD4 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV54470282; called by muse, mutect2, varscan2
- NEXMIF | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV50021520; called by muse, mutect2, varscan2
- NF1 | c.4459C>T p.P1487S (on ENST00000358273 / NM_001042492.3; = p.P1466S on NM_000267.3) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.097); catalogued as rs1265291141, COSV62191516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLGN2 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs994956773, COSV57208708; called by muse, mutect2, varscan2
- NLRP14 | c.1511C>A p.S504Y | Missense Mutation (SNP) | VAF 55/61 reads (90%) | SIFT tolerated (0.66); PolyPhen benign (0.181); catalogued as COSV55063572, COSV55068248; called by muse, mutect2, varscan2
- NLRP5 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as rs577761633, COSV66761737; called by muse, mutect2, varscan2
- NLRP8 | c.2573G>A p.S858N | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.122); catalogued as COSV52582775; called by muse, varscan2
- NMNAT3 | c.43T>A p.F15I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1190980347, COSV99951540; called by muse, mutect2, varscan2
- NMUR2 | c.967A>C p.N323H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54916814; called by muse, mutect2, varscan2
- NOS1 | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV57605768; called by muse, mutect2, varscan2
- NPNT | c.1649G>A p.G550E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV59751444, COSV59756889; called by muse, mutect2, varscan2
- NPS | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs865939340, COSV67690454; called by muse, mutect2, varscan2
- NRXN1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs1207537332, COSV58434279; called by muse, mutect2, varscan2
- NRXN3 | c.1442A>G p.N481S (on ENST00000335750 / NM_001330195.2; = p.N108S on NM_004796.6) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs144756457; called by muse, mutect2, varscan2
- NSL1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.899); catalogued as COSV65327788; called by muse, mutect2, varscan2
- OBP2B | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64402161; called by muse, mutect2, varscan2
- OGDHL | c.2761C>A p.P921T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65100572; called by muse, mutect2, varscan2
- OGDHL | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65100576; called by muse, mutect2, varscan2
- OLAH | c.629C>T p.S210F (on ENST00000378228 / NM_001039702.3; = p.S263F on NM_018324.3) | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV65491235; called by muse, mutect2, varscan2
- OLFM2 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1343565418, COSV53428240; called by muse, mutect2, varscan2
- OPRPN | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 81/172 reads (47%) | catalogued as rs201862662, COSV68192531; called by muse, mutect2, varscan2
- OR10A3 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs866622532, COSV62459092; called by muse, mutect2, varscan2
- OR10K1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs142494640; called by muse, mutect2, varscan2
- OR10Z1 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.713); catalogued as COSV63523699; called by muse, mutect2, varscan2
- OR11H4 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs367693071, COSV59559703; called by muse, mutect2, varscan2
- OR11L1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV63313443; called by muse, mutect2, varscan2
- OR12D3 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65826211; called by muse, mutect2, varscan2
- OR13D1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 71/80 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772318324, COSV100598632, COSV59513383; called by muse, varscan2
- OR2M5 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 95/323 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV63545545, COSV63546003; called by muse, mutect2, varscan2
- OR2T10 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV57895990; called by muse, mutect2, varscan2
- OR2V2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.674); catalogued as COSV60314628; called by muse, mutect2, varscan2
- OR4C13 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV73648600; called by muse, mutect2, varscan2
- OR4K1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs149331048, COSV53458632, COSV53459042; called by muse, mutect2, varscan2
- OR4M1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV60059274; called by muse, mutect2, varscan2
- OR52A1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV61091903; called by muse, mutect2, varscan2
- OR52E8 | c.815A>T p.N272I | Missense Mutation (SNP) | VAF 73/80 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV66204335; called by muse, mutect2, varscan2
- OR5B3 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV58676217; called by muse, mutect2, varscan2
- OR6T1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770876608, COSV58305477; called by muse, mutect2, varscan2
- OR7G1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs769414989, COSV53316818; called by muse, mutect2, varscan2
- OR8K1 | c.543C>G p.S181R | Missense Mutation (SNP) | VAF 68/75 reads (91%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.02); catalogued as rs748269286, COSV54401212, COSV54405024; called by muse, mutect2, varscan2
- OR9A4 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV71884912; called by muse, mutect2, varscan2
- P4HA1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54958001; called by muse, mutect2, varscan2
- PASD1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 30/30 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.076); catalogued as rs865853470, COSV64853861; called by muse, mutect2, varscan2
- PAX2 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1369347741, COSV62289966; called by muse, mutect2, varscan2
- PCDHA10 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.236); catalogued as rs1358871197, COSV56474595; called by muse, mutect2, varscan2
- PCDHA11 | c.1180T>A p.F394I | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV56474612; called by muse, mutect2, varscan2
- PCDHA12 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); catalogued as COSV56474622; called by muse, mutect2, varscan2
- PCDHB3 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV50563880; called by muse, mutect2, varscan2
- PCDHB8 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as rs782167467, COSV50753501, COSV99175411; called by muse, mutect2, varscan2
- PCDHGA7 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV53892169; called by muse, mutect2, varscan2
- PCDHGB3 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 37/89 reads (42%) | catalogued as COSV53892160, COSV53953403, COSV54003760; called by muse, mutect2, varscan2
- PCK2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs201059299, COSV53748994, COSV53749409; called by muse, mutect2, varscan2
- PCLO | c.5626A>T p.K1876* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV61612758; called by muse, mutect2, varscan2
- PCNX3 | c.3615C>A p.F1205L | Missense Mutation (SNP) | VAF 107/116 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV63134334; called by muse, mutect2, varscan2
- PCNX4 | c.1987C>T p.R663C (on ENST00000406854 / NM_001330177.2; = p.R429C on NM_022495.5) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747512999, COSV58302068; called by muse, mutect2, varscan2
- PDE6A | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54924151; called by muse, mutect2, varscan2
- PGM1 | c.337A>T p.I113F | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100936649, COSV64299967; called by muse, mutect2, varscan2
- PHKA1 | c.2756G>A p.R919Q | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349683999, COSV59801196; called by muse, mutect2, varscan2
- PIK3CA | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV55874169; called by muse, mutect2, varscan2
- PKHD1L1 | c.10459T>A p.Y3487N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV65736090; called by muse, mutect2, varscan2
- PLCB2 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53030450; called by muse, mutect2, varscan2
- PLCZ1 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV56848329; called by muse, mutect2, varscan2
- PLIN1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.807); catalogued as rs1567077484, COSV55582691, COSV55584566; called by muse, mutect2, varscan2
- PLXDC2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV65900278; called by muse, mutect2, varscan2
- PLXNA4 | c.4628C>T p.S1543F | Missense Mutation (SNP) | VAF 79/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100324457, COSV58102320; called by muse, mutect2, varscan2
- POU6F2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as rs1238541963, COSV68866878; called by muse, mutect2, varscan2
- PPARG | c.1270+1G>A p.X424_splice (on ENST00000287820 / NM_015869.5; = p.X394_splice on NM_005037.7) | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as COSV55140672; called by muse, mutect2
- PPP1R3A | c.2867C>T p.S956L | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52875102; called by muse, varscan2
- PRAMEF17 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs989031993; called by muse, mutect2, varscan2
- PRC1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 36/71 reads (51%) | catalogued as COSV62693980, COSV62696025; called by muse, mutect2, varscan2
- PREX2 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.182); catalogued as COSV55748740; called by muse, mutect2, varscan2
- PRKDC | c.6482C>G p.A2161G | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349182758, COSV58041121; called by muse, mutect2, varscan2
- PRKG1 | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV64765869; called by muse, mutect2, varscan2
- PROX2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV101507799; called by muse, mutect2, varscan2
- PROX2 | c.1278G>A p.M426I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1162358441, COSV101507800; called by muse, mutect2, varscan2
- PSAT1 | c.973C>T p.L325F | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV61301788; called by muse, mutect2, varscan2
- PSIP1 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66253477; called by muse, mutect2, varscan2
- PTGS2 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV66568110; called by muse, mutect2, varscan2
- PTPRC | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV61405678; called by muse, mutect2, varscan2
- PYROXD1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53707852; called by muse, mutect2, varscan2
- QRSL1 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759025160, COSV64686905; called by muse, mutect2, varscan2
- RAB11FIP2 | c.448A>T p.S150C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62924731; called by muse, mutect2, varscan2
- RAB15 | c.346A>C p.K116Q (on ENST00000533601 / NM_001308154.2; = p.R159S on NM_198686.3) | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV50824074; called by muse, mutect2, varscan2
- RAB27B | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV50494213; called by muse, mutect2, varscan2
- RAC1 | c.93A>T p.E31D | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.102); catalogued as COSV61821577, COSV61822534; called by muse, mutect2, varscan2
- RAPGEF1 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV64697331; called by muse, mutect2, varscan2
- RASGRP4 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV53093831; called by muse, mutect2
- RELN | c.8470C>T p.P2824S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.936); catalogued as rs1224908089, COSV100633044, COSV58983743; called by muse, mutect2, varscan2
- REPS2 | c.1921C>T p.H641Y | Missense Mutation (SNP) | VAF 100/111 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58178240; called by muse, mutect2, varscan2
- RGS7BP | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV61833218; called by muse, mutect2, varscan2
- RIPK2 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.428); catalogued as rs202080836, COSV55131264; called by muse, mutect2, varscan2
- ROR1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as rs371110337; called by muse, mutect2, varscan2
- ROS1 | c.5429C>T p.S1810F | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1256569613, COSV63850752; called by muse, mutect2, varscan2
- RPL13 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51947293; called by muse, mutect2, varscan2
- RRAGB | c.931C>T p.Q311* (on ENST00000262850 / NM_016656.4; = p.Q283* on NM_006064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/18 reads (89%) | catalogued as COSV53328313; called by muse, mutect2, varscan2
- RRNAD1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63928603; called by muse, mutect2, varscan2
- RSPO2 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs776068927, COSV52637198; called by muse, mutect2, varscan2
- RXFP1 | c.900G>A p.L300= | Splice Region (SNP) | VAF 11/34 reads (32%) | catalogued as COSV57045948; called by muse, mutect2, varscan2
- RYR1 | c.8720C>T p.P2907L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62087254; called by muse, mutect2, varscan2
- SAAL1 | c.1069A>C p.I357L | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.5); PolyPhen benign (0.085); catalogued as COSV100253805; called by muse, mutect2, varscan2
- SAMD9 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV66072711; called by muse, mutect2, varscan2
- SBNO1 | c.2167G>A p.G723S (on ENST00000420886; = p.G722S on NM_018183.5) | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV57338473; called by muse, mutect2, varscan2
- SCFD1 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as COSV61722025; called by muse, mutect2, varscan2
- SCN3A | c.4849C>T p.P1617S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51800385; called by muse, mutect2, varscan2
- SCN5A | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV61114841; called by muse, mutect2, varscan2
- SDC4 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.7); PolyPhen benign (0.177); catalogued as rs765053382, COSV65594919; called by muse, mutect2, varscan2
- SDK2 | c.5398C>T p.R1800C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1266015702, COSV66180522; called by muse, mutect2, varscan2
- SDR16C5 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV58125191, COSV58126293; called by muse, varscan2
- SELENBP1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64372872; called by muse, mutect2, varscan2
- SEMG1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.973); catalogued as COSV54874059; called by muse, mutect2, varscan2
- SEMG2 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.926); catalogued as rs146527428; called by muse, mutect2, varscan2
- SERPINA10 | c.581A>T p.N194I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56227323; called by muse, mutect2, varscan2
- SERPINH1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV63997580; called by muse, mutect2, varscan2
- SERTM1 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV59375564; called by muse, mutect2, varscan2
- SEZ6L | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV104374047, COSV50657615; called by muse, mutect2, varscan2
- SIPA1L1 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV62168132; called by muse, mutect2, varscan2
- SLC12A5 | c.995G>A p.G332E (on ENST00000454036 / NM_001134771.2; = p.G309E on NM_020708.5) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs1371576683, COSV54787070; called by muse, mutect2, varscan2
- SLC15A2 | c.1660G>A p.G554R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs1474568739, COSV55195482, COSV99815858; called by muse, mutect2, varscan2
- SLC22A14 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV56196067; called by muse, mutect2, varscan2
- SLC22A9 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 37/39 reads (95%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54165488; called by muse, mutect2, varscan2
- SLC25A21 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV58713792; called by muse, mutect2, varscan2
- SLC27A6 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs767486421, COSV52478998; called by muse, mutect2, varscan2
- SLC6A12 | c.1057T>G p.S353A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.029); catalogued as COSV62883713; called by muse, mutect2, varscan2
- SLC8A3 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63518602; called by muse, mutect2
- SLC9A4 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54828502; called by muse, varscan2
- SLC9A4 | c.1143G>A p.W381* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV54828512; called by muse, varscan2
- SLIT3 | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV60590642; called by muse, mutect2, varscan2
- SMIM15 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59120128; called by muse, mutect2, varscan2
- SOX17 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52023969; called by muse, mutect2
- SOX17 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52023978; called by muse, mutect2
- SP100 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.874); catalogued as COSV50974357; called by muse, mutect2, varscan2
- SP4 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as rs780725413, COSV56020344; called by muse, mutect2, varscan2
- SPOCD1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.076); catalogued as COSV57093426; called by muse, mutect2, varscan2
- SPPL2C | c.1570C>T p.L524F | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV61291652, COSV61292913; called by muse, mutect2, varscan2
- SPRR3 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV54878208; called by muse, mutect2, varscan2
- ST18 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs530224297, COSV52483123; called by muse, mutect2, varscan2
- ST6GAL1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | PolyPhen benign (0.017); catalogued as COSV51465521; called by muse, mutect2, varscan2
- ST8SIA6 | c.748A>T p.K250* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV66465329; called by muse, mutect2, varscan2
- STAB2 | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as rs748776950, COSV66333493, COSV66341104; called by muse, mutect2, varscan2
- STAT4 | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61827570; called by muse, mutect2, varscan2
- STOX1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53812597; called by muse, mutect2, varscan2
- STPG2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV54783332; called by muse, mutect2, varscan2
- STX11 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1204079066, COSV62448387; called by muse, mutect2, varscan2
- SULF2 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 88/148 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs760729379, COSV63413560; called by muse, mutect2, varscan2
- SULT1E1 | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs1172688138, COSV56945907; called by muse, mutect2, varscan2
- SVEP1 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57027654; called by muse, mutect2, varscan2
- SVEP1 | c.2822G>A p.R941Q | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757833118, COSV57027682; called by muse, mutect2, varscan2
- SWT1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV62252661; called by muse, mutect2, varscan2
- SYNE2 | c.6019G>A p.E2007K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.239); catalogued as COSV59938279; called by muse, mutect2, varscan2
- SYNE2 | c.18137C>T p.S6046F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59938285; called by muse, mutect2, varscan2
- SYNPO2 | c.2863G>A p.G955R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs868694258, COSV61105696; called by muse, mutect2, varscan2
- SYT12 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV67353205; called by muse, mutect2, varscan2
- TACR3 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100510296; called by muse, mutect2, varscan2
- TAFA1 | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as COSV72036807; called by muse, mutect2, varscan2
- TBC1D9 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1410640443, COSV71306711; called by muse, mutect2
- TCHHL1 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV64284718; called by muse, mutect2, varscan2
- TFEB | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1445719642, COSV100026084, COSV57824364; called by muse, mutect2, varscan2
- TFPI2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV55989748; called by muse, mutect2, varscan2
- TGM5 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.84); PolyPhen benign (0.037); catalogued as COSV55008296; called by muse, mutect2, varscan2
- THBS1 | c.3170G>A p.G1057E | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52949651; called by muse, mutect2, varscan2
- THRB | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as rs1559441969, COSV54978896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TINAG | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52505025; called by muse, mutect2, varscan2
- TLK2 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.927); catalogued as COSV58296884; called by muse, mutect2, varscan2
- TLR7 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs144771387, COSV101027805; called by muse, varscan2
- TM6SF2 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.493); catalogued as COSV52268246; called by muse, mutect2, varscan2
- TM7SF3 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58001158; called by muse, mutect2, varscan2
- TMPRSS7 | c.1945C>T p.H649Y (on ENST00000452346; = p.H523Y on NM_001042575.2) | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.212); catalogued as COSV69979407, COSV69979786; called by muse, mutect2, varscan2
- TNFRSF11B | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as COSV52069106; called by muse, mutect2, varscan2
- TNFSF11 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV53476331; called by muse, mutect2, varscan2
- TNFSF9 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV55537672; called by muse, mutect2, varscan2
- TNS2 | c.2722C>T p.P908S (on ENST00000314250 / NM_170754.4; = p.P918S on NM_015319.2) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as COSV56852094; called by muse, mutect2, varscan2
- TONSL | c.3427G>T p.D1143Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV68047495; called by muse, mutect2, varscan2
- TOX | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV63841910; called by muse, mutect2, varscan2
- TP63 | c.1664G>A p.R555K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.636); catalogued as COSV53195337; called by muse, mutect2, varscan2
- TPO | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as CS002686, COSV61093388; called by muse, mutect2, varscan2
- TPRG1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1560591341, COSV61462969; called by muse, mutect2, varscan2
- TRAPPC11 | c.3301C>T p.P1101S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV58214289; called by muse, mutect2, varscan2
- TRPC5 | c.1411A>T p.M471L | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV53282990; called by muse, mutect2, varscan2
- TRPC7 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV61452049; called by muse, mutect2, varscan2
- TSNAXIP1 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54647995; called by muse, mutect2
- TSPO2 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV55108803; called by muse, mutect2, varscan2
- TTC27 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV58648344; called by muse, mutect2, varscan2
- TTN | c.32326G>A p.E10776K (on ENST00000591111; = p.E9849K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | PolyPhen probably damaging (0.991); catalogued as rs1223983021, COSV59862637; called by muse, mutect2, varscan2
- TTN | c.23093C>T p.S7698L (on ENST00000591111; = p.S6771L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/111 reads (40%) | PolyPhen benign (0.011); catalogued as COSV59862653; called by muse, mutect2, varscan2
- TTN | c.14198G>A p.G4733E (on ENST00000591111; = p.G3806E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | PolyPhen probably damaging (0.99); catalogued as COSV59862665; called by muse, mutect2, varscan2
- UBE2Q2 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51191701; called by muse, mutect2, varscan2
- UBR4 | c.11269C>T p.R3757W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779231802, COSV64382072; called by muse, mutect2, varscan2
- UBTD2 | c.416T>A p.L139Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.328); catalogued as COSV67142565; called by muse, mutect2, varscan2
- UBXN7 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56353454, COSV99580966; called by muse, mutect2, varscan2
- UGT1A1 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.665); catalogued as COSV59380701; called by muse, mutect2, varscan2
- UGT2B15 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57732745; called by muse, mutect2, varscan2
- UGT3A1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs754987941, COSV57095662, COSV57098440; called by muse, mutect2
- UNC79 | c.4939G>A p.E1647K (on ENST00000393151 / NM_001346218.2; = p.E1470K on NM_020818.5) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV56371866; called by muse, mutect2, varscan2
- UNC93A | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV57806767; called by muse, mutect2, varscan2
- USF3 | c.4850C>T p.S1617L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); catalogued as COSV57069332; called by muse, mutect2, varscan2
- USP22 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV54945323; called by muse, mutect2, varscan2
- USP31 | c.3208C>T p.P1070S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV54848832; called by muse, mutect2, varscan2
- USP8 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as COSV56161822; called by muse, mutect2, varscan2
- VCAN | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); catalogued as rs143341095; ClinVar: uncertain significance; called by muse, varscan2
- VPS37B | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs777520018, COSV53438781; called by muse, mutect2, varscan2
- VWF | c.5456G>A p.R1819K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.989); catalogued as rs767687582, COSV54618739; called by muse, varscan2
- WNK3 | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 38/39 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV63611832; called by muse, mutect2, varscan2
- XIRP1 | c.1687C>T p.H563Y | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61136647; called by muse, mutect2, varscan2
- XIRP2 | c.6067G>A p.D2023N (on ENST00000628543; = p.D2198N on NM_152381.6) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54679852; called by muse, mutect2, varscan2
- XIRP2 | c.6790G>A p.D2264N (on ENST00000628543; = p.D2439N on NM_152381.6) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs563915541, COSV54679859; called by muse, mutect2, varscan2
- ZC3H7B | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.219); catalogued as COSV60960208; called by muse, mutect2, varscan2
- ZFHX4 | c.4856C>G p.T1619R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50478820; called by muse, mutect2, varscan2
- ZNF135 | c.790C>T p.H264Y (on ENST00000313434 / NM_001289401.2; = p.H276Y on NM_003436.4) | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1384514546, COSV57879762; called by muse, varscan2
- ZNF224 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs763697043, COSV61241404; called by muse, mutect2, varscan2
- ZNF239 | c.420T>G p.N140K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60017914; called by muse, mutect2, varscan2
- ZNF292 | c.5660C>T p.S1887F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60535039; called by muse, mutect2, varscan2
- ZNF331 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53474349; called by muse, mutect2, varscan2
- ZNF350 | c.1256A>G p.K419R | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV54707381; called by muse, mutect2, varscan2
- ZNF385B | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV69800100, COSV69800409; called by muse, mutect2, varscan2
- ZNF391 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV55121212; called by muse, mutect2, varscan2
- ZNF496 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV54173104; called by muse, mutect2, varscan2
- ZNF503 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65306914; called by muse, mutect2, varscan2
- ZNF594 | c.2214T>A p.C738* | Nonsense Mutation (SNP) | VAF 42/158 reads (27%) | catalogued as COSV68384652; called by muse, mutect2, varscan2
- ZNF662 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV60240970; called by muse, mutect2, varscan2
- ZNF678 | c.1279C>T p.H427Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59379848; called by muse, mutect2, varscan2
- ZNF684 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs1202681640, COSV65518769; called by muse, mutect2
- ZNF707 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100690564; called by muse, mutect2, varscan2
- ZNF707 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV100690567; called by muse, mutect2, varscan2
- ZNF718 | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs782717828, COSV68140223; called by muse, mutect2, varscan2
- ZNF749 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.434); catalogued as COSV100494276; called by muse, mutect2, varscan2
- ZNF749 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.312); catalogued as COSV100494278; called by muse, mutect2, varscan2
- ZNF804A | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV56433650; called by muse, mutect2, varscan2
- ZNF804A | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs1300852164, COSV56433664; called by muse, mutect2, varscan2
- ZNF98 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63333864; called by muse, mutect2, varscan2
- ZP3 | c.208G>A p.D70N (on ENST00000394857 / NM_001110354.2; = p.D19N on NM_007155.6) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV60630096; called by muse, mutect2, varscan2
- ZPLD1 | c.697G>A p.D233N (on ENST00000466937 / NM_001329788.1; = p.D249N on NM_175056.2) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60351531; called by muse, mutect2, varscan2
- IGHV5-51 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- KLHL9 | c.1294del p.M432* | Frame Shift Del (DEL) | VAF 73/112 reads (65%) | called by mutect2, pindel, varscan2
- PCDHB14 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.177); called by muse, mutect2
- PHIP | c.4512del p.R1505Efs*9 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | called by mutect2, pindel, varscan2
- SH2D7 | c.553dup p.R185Pfs*41 | Frame Shift Ins (INS) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- ABCA8 | c.3927G>A p.L1309= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV52193173; called by muse, mutect2, varscan2
- ABCC11 | c.2829C>T p.V943= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs774785973, COSV62321015; called by muse, mutect2, varscan2
- ABCC5 | c.3021C>T p.I1007= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1177251349, COSV55586629; called by muse, mutect2, varscan2
- AC011448.1 | c.591C>T p.G197= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV52272142; called by muse, mutect2, varscan2
- ACAA1 | c.1026C>T p.F342= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs779832294, COSV57169488; called by muse, mutect2, varscan2
- ACP6 | c.1044T>C p.F348= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV65076145; called by muse, mutect2, varscan2
- ACSM1 | c.306C>T p.F102= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs768165014, COSV54632726; called by muse, mutect2, varscan2
- ACSM2B | c.1668G>A p.G556= | Silent (SNP) | VAF 64/77 reads (83%) | catalogued as rs868198296, COSV61656505; called by muse, mutect2, varscan2
- ADAD2 | c.1278C>T p.I426= (on ENST00000315906 / NM_001145400.2; = p.I508= on NM_139174.4) | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV51892269; called by muse, mutect2, varscan2
- ADGRB3 | c.3451C>A p.R1151= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV53233029, COSV53255498; called by muse, mutect2, varscan2
- ADGRF1 | c.114G>A p.K38= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV64799378; called by muse, mutect2, varscan2
- ADGRF3 | c.2148C>T p.V716= (on ENST00000311519 / NM_001145168.1; = p.V517= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV61048625; called by muse, mutect2, varscan2
- ADORA1 | c.687G>A p.E229= | Silent (SNP) | VAF 69/104 reads (66%) | catalogued as COSV55141057; called by muse, mutect2, varscan2
- AIFM3 | c.66G>A p.K22= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV58997186; called by muse, mutect2, varscan2
- AKR1D1 | c.372C>T p.A124= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV54335930; called by muse, mutect2, varscan2
- ANKEF1 | c.693C>T p.F231= | Silent (SNP) | VAF 57/98 reads (58%) | catalogued as rs368002362; called by muse, mutect2, varscan2
- ANKRD34B | c.60G>A p.Q20= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV58613263; called by muse, mutect2, varscan2
- ANPEP | c.508C>T p.L170= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV100262734, COSV55588959; called by muse, mutect2, varscan2
- AOX1 | c.2844G>A p.E948= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1337331096, COSV65979779; called by muse, mutect2, varscan2
- AQP5 | c.582G>A p.V194= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV53310509; called by muse, mutect2, varscan2
- ASH1L | c.3054C>T p.L1018= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV64204944; called by muse, mutect2, varscan2
- ASTN2 | c.1008G>A p.E336= | Silent (SNP) | VAF 110/114 reads (96%) | catalogued as rs1262325424, COSV57747406; called by muse, mutect2, varscan2
- ATP6V1G2 | c.132G>A p.V44= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV58214009; called by muse, mutect2, varscan2
- ATP8B4 | c.1809G>A p.L603= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as COSV52708281; called by muse, mutect2, varscan2
- AXL | c.336G>A p.T112= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs751357344, COSV56563219; called by muse, mutect2, varscan2
- BACH2 | c.318C>T p.I106= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV57582895; called by muse, mutect2, varscan2
- BCL9 | c.3624G>A p.G1208= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs1229597874, COSV52340308; called by muse, mutect2, varscan2
- BIN2 | c.1122G>A p.L374= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs754220615, COSV57203385; called by muse, mutect2, varscan2
- BRINP1 | c.966C>T p.F322= | Silent (SNP) | VAF 33/41 reads (80%) | catalogued as COSV56290872; called by muse, mutect2, varscan2
- BRINP3 | c.49C>T p.L17= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV66511633; called by muse, mutect2, varscan2
- BTNL3 | c.312C>T p.I104= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV61564232; called by muse, mutect2, varscan2
- BZW2 | c.816C>T p.I272= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV51753599; called by muse, mutect2, varscan2
- CA2 | c.765C>T p.I255= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV53405608; called by muse, mutect2, varscan2
- CACNA1C | c.1752C>T p.F584= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs886043677, COSV59694388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.471C>T p.F157= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV54943956, COSV54947872; called by muse, mutect2, varscan2
- CAD | c.3726C>T p.I1242= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs773059833, COSV53023119; called by muse, mutect2, varscan2
- CALCRL | c.666G>A p.L222= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1051545619, COSV66473241; called by muse, mutect2, varscan2
- CAMK2A | c.1395C>T p.V465= (on ENST00000348628 / NM_171825.2; = p.V476= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs202174183, COSV62244827; called by muse, mutect2
- CAPN10 | c.1980C>T p.F660= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV54374636; called by muse, mutect2, varscan2
- CARD11 | c.249G>A p.K83= | Silent (SNP) | VAF 96/231 reads (42%) | catalogued as COSV62716173; called by muse, mutect2, varscan2
- CCDC60 | c.1486C>T p.L496= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV59539321; called by muse, mutect2, varscan2
- CD163 | c.495G>A p.G165= | Silent (SNP) | VAF 67/151 reads (44%) | catalogued as rs766179361, COSV63129001; called by muse, mutect2, varscan2
- CDH8 | c.288C>T p.I96= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV54845324, COSV54848241; called by muse, mutect2, varscan2
- CEACAM5 | c.2067C>T p.V689= | Silent (SNP) | VAF 141/335 reads (42%) | catalogued as rs1445524498, COSV55750358; called by muse, mutect2, varscan2
- CENPJ | c.2709C>T p.S903= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV101121489; called by muse, mutect2, varscan2
- CEP162 | c.1011C>T p.I337= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV57616843; called by muse, mutect2, varscan2
- CFAP58 | c.2580G>A p.G860= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV63832373; called by muse, mutect2, varscan2
- CFAP74 | c.399C>T p.A133= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs368597015; called by muse, mutect2, varscan2
- CLCN6 | c.2193C>T p.T731= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV56737637; called by muse, mutect2, varscan2
- CLSTN3 | c.1065C>T p.P355= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV56933646; called by muse, mutect2, varscan2
- CNGA3 | c.1683G>A p.G561= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs771259045, COSV55621852; called by muse, mutect2, varscan2
- CNNM3 | c.1323C>T p.I441= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs755157253, COSV59708580; called by muse, mutect2, varscan2
- CNTN6 | c.606G>A p.E202= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV63160321; called by muse, mutect2, varscan2
- COL15A1 | c.2118G>A p.G706= | Silent (SNP) | VAF 55/58 reads (95%) | catalogued as COSV66640926; called by muse, mutect2, varscan2
- COL15A1 | c.3328C>T p.L1110= | Silent (SNP) | VAF 44/45 reads (98%) | catalogued as COSV66640933, COSV66648827; called by muse, mutect2, varscan2
- COL17A1 | c.1086C>T p.I362= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100793138, COSV62225010; called by muse, mutect2
- COL5A2 | c.4332C>T p.I1444= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs138837670; called by muse, mutect2, varscan2
- CPNE9 | c.837C>T p.S279= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV56067442; called by muse, mutect2, varscan2
- CSMD3 | c.9747C>T p.F3249= (on ENST00000297405 / NM_001363185.1; = p.F3080= on NM_052900.3) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs61754530, COSV52091126; called by muse, mutect2, varscan2
- CTAGE1 | c.1690C>T p.L564= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs189335114, COSV66942789; called by muse, mutect2, varscan2
- CUL9 | c.3825G>A p.Q1275= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV52724457; called by muse, mutect2, varscan2
- CYFIP2 | c.3345C>T p.S1115= (on ENST00000616178 / NM_001291722.2; = p.S1090= on NM_014376.4) | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV59026866; called by muse, mutect2, varscan2
- CYP4A22 | c.54C>T p.I18= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV53737774; called by muse, mutect2, varscan2
- CYP4A22 | c.582G>A p.L194= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV53737788; called by muse, mutect2, varscan2
- CYTIP | c.903G>A p.R301= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs1341505439, COSV51631780; called by muse, mutect2, varscan2
- DAAM1 | c.3183C>T p.T1061= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV62833825; called by muse, mutect2, varscan2
- DAB1 | c.1461G>A p.Q487= (on ENST00000371231; = p.Q454= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100976230, COSV64689669; called by muse, mutect2, varscan2
- DDX19B | c.937C>T p.L313= | Silent (SNP) | VAF 59/114 reads (52%) | catalogued as COSV55362497, COSV55366275; called by muse, mutect2, varscan2
- DDX50 | c.1101C>T p.I367= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV65291622; called by muse, mutect2, varscan2
- DDX60 | c.2499G>A p.T833= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs746559865, COSV67094881; called by muse, mutect2, varscan2
- DIP2B | c.4143C>T p.T1381= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV56578116; called by muse, mutect2, varscan2
- DIRAS2 | c.327G>A p.G109= | Silent (SNP) | VAF 63/70 reads (90%) | catalogued as COSV65370635; called by muse, mutect2, varscan2
- DNAH3 | c.10185C>T p.F3395= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs758503370, COSV54500949; called by muse, mutect2, varscan2
- DNAH5 | c.12324C>T p.F4108= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV54201346; called by muse, mutect2, varscan2
- DNAH5 | c.10053G>A p.Q3351= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV54201371, COSV54250907; called by muse, mutect2, varscan2
- DNAH5 | c.8172C>T p.F2724= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV54201380, COSV54257640; called by muse, mutect2, varscan2
- DPRX | c.405C>T p.P135= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV64949152; called by muse, mutect2, varscan2
- DPYD | c.1770C>T p.I590= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV64589548; called by muse, mutect2, varscan2
- DRC7 | c.756G>A p.R252= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV61052758; called by muse, mutect2, varscan2
- DSG1 | c.798C>T p.I266= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV57132922; called by muse, mutect2, varscan2
- DYNC1H1 | c.8499C>T p.F2833= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1255566403, COSV64133941; called by muse, mutect2, varscan2
- EFCAB6 | c.969G>A p.K323= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53057294, COSV53065611; called by muse, mutect2, varscan2
- EMP2 | c.246C>T p.F82= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs375756110, COSV63995552; called by muse, mutect2, varscan2
- EPB41L1 | c.2286C>T p.S762= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs764008099, COSV52433006; called by muse, mutect2, varscan2
- EPHA6 | c.1773C>T p.A591= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV67556776; called by muse, mutect2, varscan2
- ERBB4 | c.795C>T p.T265= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV53498128, COSV53561202; called by muse, mutect2, varscan2
- ERCC2 | c.1233C>T p.A411= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs754028681, COSV55538404; called by muse, mutect2, varscan2
- ERCC6L | c.1239T>C p.H413= | Silent (SNP) | VAF 22/23 reads (96%) | catalogued as COSV57819222; called by muse, mutect2, varscan2
- ETS2 | c.993C>T p.F331= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV62872114; called by muse, mutect2, varscan2
- F13B | c.90G>A p.V30= | Silent (SNP) | VAF 68/179 reads (38%) | catalogued as COSV66372015; called by muse, mutect2, varscan2
- FAM135B | c.3594C>T p.I1198= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV52702153; called by muse, mutect2, varscan2
- FAM171A1 | c.2496G>A p.Q832= | Silent (SNP) | VAF 58/114 reads (51%) | catalogued as COSV65313192; called by muse, mutect2, varscan2
- FAM214B | c.162C>T p.S54= | Silent (SNP) | VAF 24/27 reads (89%) | catalogued as COSV59714819; called by muse, mutect2, varscan2
- FAM47A | c.2230C>T p.L744= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as COSV60493636; called by muse, mutect2, varscan2
- FCGBP | c.4203C>T p.F1401= | Silent (SNP) | VAF 20/33 reads (61%) | called by muse, varscan2
- FHIT | c.291C>T p.V97= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs1185161315, COSV59282900; called by muse, mutect2, varscan2
- FRMPD2 | c.3606C>T p.I1202= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs1287033588, COSV59714639; called by mutect2, varscan2
- FRMPD2 | c.1464G>A p.E488= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV59714645; called by muse, mutect2, varscan2
- GALR1 | c.621C>T p.F207= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as rs776511871, COSV55315541; called by muse, mutect2, varscan2
- GFRA3 | c.684G>A p.G228= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as COSV51229096, COSV99218344; called by muse, mutect2, varscan2
- GIMAP8 | c.1350G>A p.G450= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV56233796; called by muse, mutect2, varscan2
- GPR27 | c.885C>T p.L295= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs149967896; called by muse, mutect2, varscan2
- GPR39 | c.495G>A p.L165= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100256685, COSV61420674; called by muse, mutect2, varscan2
- GRIK1 | c.1476C>T p.F492= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV58709429; called by muse, mutect2, varscan2
- GSS | c.1182C>T p.S394= | Silent (SNP) | VAF 102/339 reads (30%) | catalogued as rs372082838; called by muse, mutect2, varscan2
- HAO2 | c.1035G>A p.L345= | Silent (SNP) | VAF 137/184 reads (74%) | catalogued as COSV58037661; called by muse, mutect2, varscan2
- HBS1L | c.1341C>T p.L447= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV63199907; called by muse, mutect2, varscan2
- HCK | c.720C>T p.P240= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV52940045; called by muse, mutect2, varscan2
- HDAC7 | c.1128C>T p.P376= (on ENST00000427332; = p.P415= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/136 reads (47%) | catalogued as COSV50318448; called by muse, mutect2, varscan2
- HEMK1 | c.852C>T p.L284= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs747948205, COSV51749779; called by muse, mutect2, varscan2
- HEPHL1 | c.2289G>A p.G763= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as COSV59889167; called by muse, mutect2, varscan2
- HLA-DQA1 | c.327C>T p.T109= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as rs1243272326, COSV58236960; called by muse, varscan2
- HLA-DQA1 | c.345C>T p.V115= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as COSV58236967; called by muse, mutect2, varscan2
- HMGCS2 | c.690G>A p.L230= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV65567050; called by muse, mutect2, varscan2
- HNF4A | c.129A>G p.S43= | Silent (SNP) | VAF 89/316 reads (28%) | catalogued as COSV57378794; called by muse, mutect2, varscan2
- HP | c.894T>C p.Y298= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV63325580; called by muse, mutect2, varscan2
- IGF2R | c.2256C>T p.F752= | Silent (SNP) | VAF 47/88 reads (53%) | catalogued as rs750837008, COSV63625982; called by muse, mutect2, varscan2
- IGKV2-24 | c.327G>A p.G109= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as rs112678521; called by muse, mutect2, varscan2
- IL18RAP | c.1581G>A p.V527= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV51823698; called by muse, mutect2, varscan2
- IMPDH1 | c.1341G>A p.Q447= (on ENST00000470772 / NM_001142573.2; = p.Q533= on NM_000883.4) | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV58314800; called by muse, mutect2, varscan2
- INSRR | c.3351A>G p.A1117= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV63870637; called by muse, mutect2, varscan2
- INTS1 | c.5031C>T p.I1677= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs1244762261, COSV67176178; called by muse, mutect2, varscan2
- IRX4 | c.498G>A p.K166= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV51470495; called by muse, mutect2, varscan2
- ITGAX | c.2889G>A p.R963= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV51640968, COSV99191476; called by muse, mutect2, varscan2
- IWS1 | c.738T>C p.R246= | Silent (SNP) | VAF 76/168 reads (45%) | catalogued as COSV54866258; called by muse, mutect2, varscan2
- JAG1 | c.3651C>T p.I1217= | Silent (SNP) | VAF 79/228 reads (35%) | catalogued as rs542831744, COSV54752845; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- JAKMIP2 | c.1545C>T p.L515= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV54596714, COSV99508401; called by muse, mutect2, varscan2
- KANK4 | c.2226C>T p.A742= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs143575291; called by muse, mutect2, varscan2
- KCNK5 | c.363C>T p.F121= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as rs372357819; called by muse, mutect2, varscan2
- KIAA1549 | c.1461C>T p.S487= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV54303969; called by muse, mutect2, varscan2
- KRBA1 | c.2325C>T p.P775= | Silent (SNP) | VAF 77/168 reads (46%) | catalogued as COSV99752426; called by muse, mutect2, varscan2
- KRT83 | c.1212G>A p.L404= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV53338095; called by muse, mutect2, varscan2
- KRTAP5-8 | c.186C>T p.S62= | Silent (SNP) | VAF 259/274 reads (95%) | catalogued as COSV68324370; called by muse, mutect2, varscan2
- LILRB5 | c.1071G>A p.K357= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV60254189; called by muse, mutect2, varscan2
- LMTK2 | c.2910G>T p.S970= | Silent (SNP) | VAF 86/190 reads (45%) | catalogued as COSV51989581, COSV51991762; called by muse, mutect2, varscan2
- LOXL4 | c.1644G>A p.L548= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV53254818; called by muse, mutect2, varscan2
- LRP1 | c.12768C>T p.C4256= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV99675277; called by muse, varscan2
- LRP1 | c.12769C>A p.R4257= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs1318986058, COSV99675279; called by muse, varscan2
- LRP1B | c.11694C>T p.I3898= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV67182156; called by muse, mutect2, varscan2
- LRP1B | c.10230C>T p.I3410= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV67182179; called by muse, mutect2, varscan2
- LRRC4C | c.192G>A p.R64= | Silent (SNP) | VAF 23/26 reads (88%) | catalogued as COSV53417133; called by muse, mutect2, varscan2
- LRRK2 | c.1563G>A p.R521= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV54177954; called by muse, mutect2, varscan2
- LRRN1 | c.1332C>T p.F444= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV60012064; called by muse, mutect2, varscan2
- LZTR1 | c.1539C>T p.I513= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV53144716; called by muse, mutect2, varscan2
- MAGEA12 | c.133C>T p.L45= | Silent (SNP) | VAF 20/23 reads (87%) | catalogued as COSV63294122; called by muse, mutect2, varscan2
- MAGEC1 | c.2712C>T p.F904= | Silent (SNP) | VAF 64/70 reads (91%) | catalogued as COSV53567253; called by muse, mutect2, varscan2
- MCM5 | c.966C>T p.F322= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV53344733; called by muse, mutect2, varscan2
- MDH1B | c.964C>T p.L322= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV65588371; called by muse, mutect2, varscan2
- MECOM | c.2502G>A p.A834= (on ENST00000468789 / NM_001105078.4; = p.A1022= on NM_004991.4) | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs779331325, COSV52958403; called by muse, mutect2, varscan2
- MET | c.1602C>T p.P534= | Silent (SNP) | VAF 85/194 reads (44%) | catalogued as COSV59255866; called by muse, mutect2, varscan2
- MFSD4A | c.567G>A p.R189= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as rs866864327, COSV65655915; called by muse, mutect2, varscan2
- MGAT4C | c.1413G>A p.R471= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV59829338, COSV59830216; called by muse, mutect2, varscan2
- MORC1 | c.81C>T p.F27= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV51712973; called by muse, mutect2, varscan2
- MPP5 | c.591G>A p.L197= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV55527546; called by muse, mutect2, varscan2
- MUC16 | c.31435C>T p.L10479= | Silent (SNP) | VAF 109/247 reads (44%) | catalogued as rs778091936, COSV67440907; called by muse, mutect2, varscan2
- MYT1L | c.1338G>A p.K446= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as COSV67706404; called by muse, mutect2, varscan2
- NAA40 | c.330C>T p.I110= | Silent (SNP) | VAF 72/79 reads (91%) | catalogued as rs140498456; called by muse, mutect2, varscan2
- NAV3 | c.4380T>C p.P1460= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV57058933; called by muse, mutect2, varscan2
- NAXE | c.756C>T p.T252= | Silent (SNP) | VAF 65/212 reads (31%) | catalogued as rs754197534, COSV58038897; ClinVar: likely benign; called by muse, mutect2, varscan2
- NBAS | c.5004G>A p.R1668= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV55710920; called by muse, mutect2, varscan2
- NFE2L1 | c.996A>G p.A332= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV62582645; called by muse, mutect2, varscan2
- NIBAN1 | c.1959G>A p.E653= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV62282506; called by muse, mutect2, varscan2
- NMNAT3 | c.42C>T p.S14= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99951544; called by muse, mutect2, varscan2
- NOTUM | c.963C>T p.G321= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1395845126, COSV68825690; called by mutect2, varscan2
- NPEPL1 | c.1434C>T p.F478= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs761006655, COSV61937956; called by muse, mutect2, varscan2
- NPTX2 | c.630C>T p.T210= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs773856934, COSV55716008; called by muse, mutect2, varscan2
- NRCAM | c.1692C>T p.S564= (on ENST00000379028 / NM_001371124.1; = p.S558= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as COSV61030412; called by muse, mutect2, varscan2
- NRXN1 | c.1923G>A p.V641= | Silent (SNP) | VAF 61/153 reads (40%) | catalogued as COSV58434250, COSV58502302; called by muse, mutect2, varscan2
- NRXN1 | c.390C>T p.I130= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV67999796; called by muse, mutect2, varscan2
- NRXN3 | c.231C>T p.S77= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs773319198, COSV99817502; called by muse, mutect2, varscan2
- NTN4 | c.408C>T p.S136= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV59216790; called by muse, mutect2, varscan2
- NTN5 | c.273C>T p.I91= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV54306392; called by muse, mutect2, varscan2
- OBI1 | c.2148C>T p.S716= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV56144263, COSV99932171; called by muse, mutect2, varscan2
- OBSCN | c.22539C>T p.A7513= | Silent (SNP) | VAF 78/119 reads (66%) | catalogued as COSV62160947; called by muse, mutect2, varscan2
- OR10A4 | c.369C>T p.R123= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as rs199786534, COSV65841649; called by muse, mutect2, varscan2
- OR10G4 | c.759C>T p.P253= | Silent (SNP) | VAF 33/36 reads (92%) | catalogued as COSV57976440; called by muse, mutect2, varscan2
- OR10G7 | c.315C>T p.F105= | Silent (SNP) | VAF 101/144 reads (70%) | catalogued as COSV57865499; called by muse, mutect2, varscan2
- OR11H4 | c.12C>T p.F4= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV59559695; called by muse, mutect2, varscan2
- OR13D1 | c.546C>T p.I182= | Silent (SNP) | VAF 48/54 reads (89%) | catalogued as rs756138793, COSV100598672, COSV59513375; called by muse, varscan2
- OR13F1 | c.43C>T p.L15= | Silent (SNP) | VAF 37/47 reads (79%) | catalogued as rs760680775, COSV58250604; called by muse, mutect2, varscan2
- OR4F6 | c.834C>T p.I278= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs1430106768, COSV61026209; called by muse, mutect2, varscan2
- OR5B2 | c.553C>T p.L185= | Silent (SNP) | VAF 27/30 reads (90%) | catalogued as COSV56907358; called by muse, mutect2, varscan2
- OR6C76 | c.186G>A p.R62= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV100094028, COSV60388502; called by muse, mutect2, varscan2
- OR8G1 | c.598C>T p.L200= | Silent (SNP) | VAF 29/33 reads (88%) | catalogued as COSV58379537; called by muse, mutect2, varscan2
- PAPPA | c.2031C>T p.L677= | Silent (SNP) | VAF 140/149 reads (94%) | catalogued as rs199936887; called by muse, varscan2
- PARP12 | c.2043C>T p.S681= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV54931878; called by muse, mutect2, varscan2
- PARP8 | c.312C>T p.S104= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV55855165, COSV99891686; called by muse, mutect2, varscan2
- PCDHA8 | c.2235G>A p.V745= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV65322967; called by muse, mutect2, varscan2
- PCDHA9 | c.258G>A p.V86= | Silent (SNP) | VAF 80/226 reads (35%) | catalogued as rs1405880656, COSV65322974; called by muse, mutect2, varscan2
- PCK2 | c.156C>T p.A52= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99394237; called by muse, mutect2, varscan2
- PCNX2 | c.3405C>T p.A1135= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as rs753050544, COSV50780698, COSV50789089; called by muse, mutect2, varscan2
- PDIA2 | c.894G>A p.G298= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1407935449, COSV51982676; called by muse, mutect2, varscan2
- PDYN | c.378G>A p.L126= | Silent (SNP) | VAF 86/139 reads (62%) | catalogued as rs1359072362, COSV54100552; called by muse, mutect2, varscan2
- PHLDB2 | c.351C>T p.S117= | Silent (SNP) | VAF 102/264 reads (39%) | catalogued as COSV67307278; called by muse, mutect2, varscan2
- PIP5K1C | c.768C>T p.G256= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs1319169596, COSV58949886; called by muse, mutect2, varscan2
- PIWIL1 | c.1884C>T p.I628= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs761623698, COSV55343713; called by muse, mutect2, varscan2
- PLCB4 | c.195C>T p.I65= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs950870437, COSV53791420; called by muse, mutect2, varscan2
112 further variants in this file (0 protein-altering or splice-affecting, 92 silent, 20 other) are not listed here.
